TARGET case TARGET-30-PAPSSE — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/716d5f40-ed39-55f4-b2b8-c682ea834c2b

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.5 years (1,267 days); Year of diagnosis: 2006; Days to last follow up: 2,518 days (6.9 years); INSS stage: Stage 4.

Biospecimens (2 samples)
- Sample TARGET-30-PAPSSE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPSSE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
